CCDI case PBCRWU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/68048ab1-fbd5-41ec-96b7-b2135325be03

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Vipoma, NOS: ICD-O-3 morphology code: 8155/3; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 15.2 years (5,546 days).

Biospecimens (3 samples)
- Sample 0DXXW9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXXXD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXXXX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
